Somatic mutation profile of tumor specimen TCGA-55-8204-01A (aliquot TCGA-55-8204-01A-11D-2238-08) from TCGA case TCGA-55-8204, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 87.1 years (31,818 days).
Specimen TCGA-55-8204-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) da73d463-b49a-48ec-85cd-20583a3c14ba.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-55-8204-10A (Blood Derived Normal), aliquot TCGA-55-8204-10A-01D-2238-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fc12fe01-bdd0-48c2-865e-35717f1c4c79

The open-access MAF lists 236 somatic variants for this specimen: 175 protein-altering or splice-affecting, 56 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 155, Silent 56, Nonsense Mutation 11, Splice Site 6, Intron 3, Frame Shift Del 2, Splice Region 1, 5'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.919+1G>T p.X307_splice | Splice Site (SNP) | VAF 43/152 reads (28%) | hotspot (GDC flag); catalogued as rs1131691039, CD920913, CS107068, CS120864, COSV52683145, COSV52775982, COSV52814989; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- AARS2 | c.750-1G>A p.X250_splice | Splice Site (SNP) | VAF 15/95 reads (16%) | catalogued as COSV99771391; called by muse, mutect2, varscan2
- ABCA13 | c.5479C>T p.H1827Y | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.027); catalogued as rs367677371; called by muse, mutect2, varscan2
- ABCA7 | c.4772A>T p.Y1591F | Missense Mutation (SNP) | VAF 62/382 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV99565614; called by muse, mutect2, varscan2
- ABCA7 | c.5741G>A p.G1914E | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as COSV99565615; called by muse, mutect2, varscan2
- ADAMTS12 | c.3788C>T p.T1263M | Missense Mutation (SNP) | VAF 44/488 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.022); catalogued as rs757177041, COSV100710420, COSV61263698; called by muse, mutect2
- AGPAT1 | c.700C>G p.L234V | Missense Mutation (SNP) | VAF 26/172 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100421609; called by muse, mutect2, varscan2
- AMBP | c.79G>A p.D27N | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs377277500; called by muse, mutect2, varscan2
- AMOT | c.2350C>T p.P784S (on ENST00000371959 / NM_001113490.1; = p.P375S on NM_133265.3) | Missense Mutation (SNP) | VAF 120/523 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100494966; called by muse, mutect2, varscan2
- ANXA4 | c.946C>G p.L316V | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as COSV99247682; called by muse, mutect2, varscan2
- ARHGEF35 | c.1168G>A p.V390M | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.557); catalogued as COSV100967721; called by muse, mutect2, varscan2
- ARVCF | c.1705G>A p.E569K | Missense Mutation (SNP) | VAF 31/140 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99599163; called by muse, mutect2, varscan2
- ATP2A1 | c.763G>C p.E255Q | Missense Mutation (SNP) | VAF 30/493 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV100837277; called by muse, mutect2
- C12orf40 | c.1036A>G p.I346V | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as COSV100209958; called by muse, mutect2, varscan2
- C22orf15 | c.431G>C p.R144T | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.528); catalogued as rs1569147443, COSV100533614; called by muse, mutect2, varscan2
- CDC25B | c.1156G>C p.D386H (on ENST00000245960 / NM_021873.3; = p.D372H on NM_004358.4) | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as COSV99847842; called by muse, mutect2, varscan2
- CDH19 | c.2065G>A p.G689S | Missense Mutation (SNP) | VAF 23/157 reads (15%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.995); catalogued as COSV100051389; called by muse, mutect2, varscan2
- CDH20 | c.73C>A p.L25M | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.055); catalogued as COSV99405089; called by muse, mutect2, varscan2
- CDYL | c.939G>C p.R313S (on ENST00000328908 / NM_001368125.1; = p.R259S on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.132); catalogued as COSV100189165; called by muse, mutect2, varscan2
- CHD1L | c.892C>G p.L298V | Missense Mutation (SNP) | VAF 17/127 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.037); catalogued as COSV100787416; called by muse, mutect2, varscan2
- CKAP4 | c.1531C>A p.H511N | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.167); catalogued as COSV100952434; called by muse, mutect2, varscan2
- COL12A1 | c.5940A>T p.I1980= | Splice Region (SNP) | VAF 29/181 reads (16%) | catalogued as COSV100485851; called by muse, mutect2, varscan2
- COL12A1 | c.5593G>T p.D1865Y | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100485852; called by muse, mutect2, varscan2
- CRYBG3 | c.6815G>T p.S2272I | Missense Mutation (SNP) | VAF 34/187 reads (18%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV99476907; called by muse, mutect2, varscan2
- CSMD3 | c.1978G>A p.E660K (on ENST00000297405 / NM_001363185.1; = p.E556K on NM_052900.3) | Missense Mutation (SNP) | VAF 26/215 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.146); catalogued as COSV52325863, COSV99831993; called by muse, mutect2, varscan2
- CYLC1 | c.1840C>A p.P614T | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.232); catalogued as COSV100254500; called by muse, mutect2, varscan2
- CYP26A1 | c.34T>C p.C12R | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.603); catalogued as COSV99814673; called by muse, mutect2
- DENND6B | c.1109C>G p.S370* | Nonsense Mutation (SNP) | VAF 4/48 reads (8%) | catalogued as COSV101306064; called by muse, mutect2
- DKK1 | c.424G>C p.D142H | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); catalogued as COSV100906529; called by muse, mutect2
- DLK1 | c.741G>T p.K247N | Missense Mutation (SNP) | VAF 62/149 reads (42%) | SIFT tolerated (0.29); PolyPhen benign (0.261); catalogued as COSV100375184; called by muse, mutect2, varscan2
- DNAH5 | c.6923C>G p.A2308G | Missense Mutation (SNP) | VAF 28/368 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV99445649; called by muse, mutect2
- DNAJC14 | c.1424A>G p.N475S | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as rs1209094369, COSV99670691; called by muse, mutect2, varscan2
- DSE | c.69C>G p.Y23* | Nonsense Mutation (SNP) | VAF 14/94 reads (15%) | catalogued as COSV100528509; called by muse, mutect2
- DYNC1H1 | c.9838G>C p.E3280Q | Missense Mutation (SNP) | VAF 8/95 reads (8%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV100794780; called by muse, mutect2
- EDRF1 | c.2783T>G p.F928C (on ENST00000356792 / NM_001202438.2; = p.F894C on NM_015608.2) | Missense Mutation (SNP) | VAF 48/180 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100523413; called by muse, mutect2, varscan2
- EGFLAM | c.2115G>C p.K705N | Missense Mutation (SNP) | VAF 21/266 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV100380205; called by muse, mutect2
- ENOX2 | c.788C>T p.S263F (on ENST00000338144 / NM_001382520.1; = p.S234F on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.352); catalogued as rs1319452400, COSV100584048; called by muse, mutect2, varscan2
- ERICH3 | c.1291G>T p.V431L | Missense Mutation (SNP) | VAF 31/175 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs753593701, COSV58604164; called by muse, mutect2, varscan2
- ERVFRD-1 | c.668C>G p.S223C | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV100977377; called by muse, mutect2, varscan2
- EVI5 | c.1953G>C p.R651S | Missense Mutation (SNP) | VAF 30/193 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100945215; called by muse, mutect2, varscan2
- EYA4 | c.209G>A p.G70E | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.382); catalogued as COSV100765589, COSV100765604; called by muse, varscan2
- F13B | c.979T>C p.C327R | Missense Mutation (SNP) | VAF 30/173 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100803269; called by muse, mutect2, varscan2
- FAM169A | c.1534G>A p.E512K | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as COSV100769087; called by muse, mutect2, varscan2
- FAM207A | c.144C>G p.I48M | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.009); catalogued as COSV99384297; called by muse, mutect2, varscan2
- FASTKD2 | c.1971G>A p.M657I | Missense Mutation (SNP) | VAF 41/293 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.266); catalogued as COSV52699152, COSV99378921; called by muse, mutect2, varscan2
- FAT4 | c.10804G>T p.V3602L | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as COSV100628319; called by muse, mutect2, varscan2
- FFAR3 | c.689C>G p.T230R | Missense Mutation (SNP) | VAF 22/211 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100588176, COSV59908710; called by muse, mutect2, varscan2
- FHOD3 | c.361C>T p.R121* | Nonsense Mutation (SNP) | VAF 5/38 reads (13%) | catalogued as rs1199009842, COSV99940888; called by muse, mutect2
- FLG2 | c.4691C>A p.T1564K | Missense Mutation (SNP) | VAF 68/416 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as COSV101165801, COSV66166480; called by muse, varscan2
- FLT3 | c.2464G>T p.G822W | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54054760; called by muse, mutect2, varscan2
- FLT4 | c.509G>A p.R170H | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs754692331, COSV56116356; called by muse, mutect2, varscan2
- FOXJ3 | c.388C>G p.L130V | Missense Mutation (SNP) | VAF 32/194 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100691679; called by muse, mutect2, varscan2
- GABRR1 | c.1280T>A p.L427Q | Missense Mutation (SNP) | VAF 30/228 reads (13%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.974); catalogued as COSV101033855; called by muse, mutect2, varscan2
- GIGYF1 | c.982G>A p.E328K | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV99309224; called by muse, mutect2, varscan2
- GLI4 | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.521); catalogued as rs745456153, COSV100391002; called by muse, mutect2, varscan2
- GPR87 | c.451C>T p.R151W | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.975); catalogued as COSV53462550; called by muse, mutect2, varscan2
- GRID2 | c.1268C>A p.T423K | Missense Mutation (SNP) | VAF 27/170 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV99939859, COSV99947233; called by muse, mutect2, varscan2
- GRK7 | c.1526C>T p.A509V | Missense Mutation (SNP) | VAF 47/288 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.255); catalogued as rs763818567, COSV99379779; called by muse, mutect2, varscan2
- GRM5 | c.1623G>T p.E541D | Missense Mutation (SNP) | VAF 21/130 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100551448; called by muse, mutect2, varscan2
- HAUS5 | c.776G>C p.R259P | Missense Mutation (SNP) | VAF 17/157 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.524); catalogued as rs773299607, COSV52547333, COSV99178330; called by muse, mutect2, varscan2
- HEY2 | c.797C>A p.A266D | Missense Mutation (SNP) | VAF 98/501 reads (20%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.923); catalogued as COSV100856363; called by muse, mutect2, varscan2
- HLTF | c.2927A>G p.K976R | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.086); catalogued as COSV99936811; called by muse, mutect2, varscan2
- HLTF | c.1595A>G p.N532S | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0.113); catalogued as COSV100026810; called by muse, mutect2, varscan2
- HMCN1 | c.11425G>A p.G3809S | Missense Mutation (SNP) | VAF 42/246 reads (17%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.999); catalogued as COSV54897447, COSV54927388; called by muse, mutect2, varscan2
- HOXD3 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.037); catalogued as COSV99980077; called by muse, mutect2, varscan2
- HPR | c.401T>A p.I134N | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99930877; called by muse, mutect2, varscan2
- HTR7 | c.599C>T p.A200V | Missense Mutation (SNP) | VAF 68/235 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.753); catalogued as rs1177517415, COSV53286463, COSV53289728; called by muse, mutect2, varscan2
- IFNAR2 | c.1087G>A p.E363K | Missense Mutation (SNP) | VAF 23/156 reads (15%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as COSV99269890; called by muse, mutect2, varscan2
- IFNAR2 | c.1372G>A p.D458N | Missense Mutation (SNP) | VAF 76/461 reads (16%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as COSV99269891; called by muse, mutect2, varscan2
- IGHD | c.358G>C p.G120R | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.74); PolyPhen benign (0.223); catalogued as COSV101162850; called by muse, mutect2, varscan2
- JMJD1C | c.3611A>G p.H1204R | Missense Mutation (SNP) | VAF 13/154 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.073); catalogued as rs1456804049, COSV100550433; called by muse, mutect2
- KANK4 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.115); catalogued as rs994627427, COSV100587296; called by muse, mutect2, varscan2
- KCNJ8 | c.441G>A p.M147I | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.315); catalogued as COSV53717055, COSV99557509; called by muse, mutect2, varscan2
- KIF2C | c.1529G>T p.R510L | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as COSV100945684; called by muse, mutect2, varscan2
- KMO | c.1228G>T p.E410* | Nonsense Mutation (SNP) | VAF 29/178 reads (16%) | catalogued as COSV100087292; called by muse, mutect2, varscan2
- KRBA1 | c.313G>T p.A105S | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as COSV99752558; called by muse, mutect2
- LAIR1 | c.303C>A p.C101* | Nonsense Mutation (SNP) | VAF 50/287 reads (17%) | catalogued as COSV100479590; called by muse, mutect2, varscan2
- LAMA1 | c.1488C>A p.N496K | Missense Mutation (SNP) | VAF 27/160 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs781121049, COSV67533529, COSV67540434; called by muse, mutect2, varscan2
- LBX1 | c.569A>T p.D190V | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100929919; called by muse, mutect2, varscan2
- LRP1B | c.13705G>T p.G4569W | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1157317785, COSV101255665; called by muse, mutect2, varscan2
- LRRN3 | c.1852C>G p.Q618E | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as COSV100069672; called by muse, mutect2, varscan2
- LRRTM4 | c.375C>A p.H125Q | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.58); PolyPhen benign (0.031); catalogued as rs1344631056, COSV69140741; called by muse, mutect2, varscan2
- MAPKBP1 | c.915C>G p.F305L (on ENST00000456763 / NM_001128608.2; = p.F299L on NM_014994.3) | Missense Mutation (SNP) | VAF 57/346 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.34); catalogued as COSV99529276; called by muse, mutect2, varscan2
- MCF2 | c.2365G>T p.V789F | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as COSV100644736, COSV100644808; called by muse, mutect2, varscan2
- MED25 | c.1813C>G p.P605A | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.039); catalogued as COSV100457289; called by muse, mutect2
- MIGA2 | c.401C>T p.S134F | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765869611, COSV99477564; called by muse, mutect2, varscan2
- MPP4 | c.366G>T p.L122F | Missense Mutation (SNP) | VAF 36/279 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100206790; called by muse, mutect2, varscan2
- MRGBP | c.525C>A p.D175E | Missense Mutation (SNP) | VAF 20/198 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0.03); catalogued as COSV100978277, COSV65111717; called by muse, mutect2, varscan2
- MSH2 | c.2797A>C p.T933P | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV99253698; called by muse, mutect2, varscan2
- MTMR10 | c.2111T>C p.L704P | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV100076060; called by muse, mutect2
- MYH8 | c.3725C>G p.S1242C | Missense Mutation (SNP) | VAF 95/277 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as COSV101238376; called by muse, mutect2, varscan2
- MYOC | c.185C>A p.P62Q | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV99231451; called by muse, mutect2, varscan2
- MYPN | c.2281G>C p.E761Q | Missense Mutation (SNP) | VAF 13/185 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV100589873; called by muse, mutect2
- NDUFB11 | c.367G>A p.E123K (on ENST00000377811 / NM_001135998.3; = p.E133K on NM_019056.6) | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.629); catalogued as COSV99333296; called by muse, mutect2, varscan2
- NHS | c.1645C>T p.H549Y | Missense Mutation (SNP) | VAF 21/138 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV101196550; called by muse, mutect2, varscan2
- NKX3-1 | c.286+2T>C p.X96_splice | Splice Site (SNP) | VAF 4/22 reads (18%) | catalogued as COSV101082754; called by muse, mutect2
- NUP107 | c.1698G>T p.E566D | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.129); catalogued as COSV99971680; called by muse, mutect2, varscan2
- OR13G1 | c.754G>T p.V252L | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.168); catalogued as COSV100687201; called by muse, mutect2, varscan2
- OR14C36 | c.460G>T p.A154S | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.173); catalogued as COSV100507497; called by muse, mutect2, varscan2
- OR1E2 | c.368A>G p.Y123C | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs371708526; called by muse, mutect2, varscan2
- OR2L8 | c.167C>A p.T56K | Missense Mutation (SNP) | VAF 81/646 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.043); catalogued as COSV100594152; called by muse, mutect2, varscan2
- OR2T4 | c.172C>A p.L58I | Missense Mutation (SNP) | VAF 50/245 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.081); catalogued as COSV63543965; called by muse, mutect2, varscan2
- OSBPL7 | c.2233G>T p.E745* | Nonsense Mutation (SNP) | VAF 82/258 reads (32%) | catalogued as COSV99136534; called by muse, mutect2, varscan2
- PADI1 | c.1736C>T p.A579V | Missense Mutation (SNP) | VAF 30/183 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374308918; called by muse, mutect2, varscan2
- PDE11A | c.2491G>T p.A831S | Missense Mutation (SNP) | VAF 33/174 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.26); catalogued as rs1473852993, COSV99611803; called by muse, mutect2, varscan2
- PDZRN3 | c.1826G>T p.S609I | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.49); catalogued as COSV99728976; called by muse, mutect2, varscan2
- PGAP1 | c.1597G>A p.E533K | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV100698137; called by muse, mutect2, varscan2
- PGLYRP2 | c.922G>A p.V308M | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.385); catalogued as COSV99483948; called by muse, mutect2
- PLA2G3 | c.959G>T p.R320L | Missense Mutation (SNP) | VAF 55/373 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.041); catalogued as rs765885838, COSV99311591, COSV99311955; called by muse, mutect2, varscan2
- PRDM7 | c.740G>C p.R247T | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.13); catalogued as COSV100371140, COSV57987847; called by muse, mutect2
- PRKDC | c.8131G>A p.E2711K | Missense Mutation (SNP) | VAF 66/623 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs746188479, COSV100040074; called by muse, mutect2, varscan2
- PRPF8 | c.2563C>T p.R855W | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100517397; called by muse, mutect2, varscan2
- PUM2 | c.1354G>A p.G452R | Missense Mutation (SNP) | VAF 24/152 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (1); catalogued as COSV100163511; called by muse, mutect2, varscan2
- PUS7 | c.1470G>C p.K490N | Missense Mutation (SNP) | VAF 30/175 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.312); catalogued as COSV100708520; called by muse, mutect2, varscan2
- R3HDM2 | c.1770G>C p.R590S | Missense Mutation (SNP) | VAF 23/282 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as COSV100715073, COSV61288773; called by muse, mutect2
- RASA1 | c.1465C>T p.R489C | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99169650; called by muse, mutect2, varscan2
- RASGRF2 | c.996G>A p.M332I | Missense Mutation (SNP) | VAF 44/200 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as COSV99429002; called by muse, mutect2, varscan2
- RIC1 | c.3367C>G p.P1123A | Missense Mutation (SNP) | VAF 75/420 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99317144; called by muse, mutect2, varscan2
- RNF113A | c.385G>A p.D129N | Missense Mutation (SNP) | VAF 139/678 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); catalogued as COSV65097429; called by muse, mutect2, varscan2
- SALL1 | c.1292C>T p.P431L | Missense Mutation (SNP) | VAF 31/156 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1385166585, COSV99173351; called by muse, varscan2
- SALL1 | c.1291C>A p.P431T | Missense Mutation (SNP) | VAF 30/153 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99173356; called by muse, varscan2
- SCD5 | c.743G>T p.R248L | Missense Mutation (SNP) | VAF 22/149 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100124534; called by muse, mutect2, varscan2
- SELE | c.1390G>T p.G464* | Nonsense Mutation (SNP) | VAF 32/174 reads (18%) | catalogued as COSV100324692, COSV60976179; called by muse, mutect2, varscan2
- SEMA5B | c.1712C>T p.P571L | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs142815872; called by muse, mutect2, varscan2
- SEPTIN2 | c.146G>A p.G49E | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100764931; called by mutect2, varscan2
- SETD2 | c.4871C>G p.S1624C | Missense Mutation (SNP) | VAF 36/158 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57432223, COSV57449759; called by muse, mutect2, varscan2
- SH3BP5L | c.659G>T p.G220V | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT tolerated (0.9); PolyPhen benign (0.003); catalogued as rs1356465565, COSV100821997; called by muse, mutect2, varscan2
- SHPRH | c.4274G>A p.G1425E (on ENST00000275233 / NM_001042683.3; = p.G1429E on NM_173082.3) | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99261931; called by muse, mutect2, varscan2
- SLC12A1 | c.2077A>G p.T693A | Missense Mutation (SNP) | VAF 36/239 reads (15%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV101118570; called by muse, mutect2, varscan2
- SLC39A10 | c.2407C>T p.L803F | Missense Mutation (SNP) | VAF 27/201 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100414872; called by muse, mutect2, varscan2
- SLC39A12 | c.590G>T p.S197I | Missense Mutation (SNP) | VAF 25/128 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.235); catalogued as COSV101070028; called by muse, mutect2, varscan2
- SLC5A8 | c.806C>T p.S269F | Missense Mutation (SNP) | VAF 23/166 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV101610540; called by muse, mutect2, varscan2
- SLC6A18 | c.523G>A p.D175N | Missense Mutation (SNP) | VAF 22/275 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV99722249; called by muse, mutect2
- SLCO2A1 | c.1877G>A p.W626* | Nonsense Mutation (SNP) | VAF 17/80 reads (21%) | catalogued as COSV100188885; called by muse, mutect2, varscan2
- SLX4 | c.5335C>T p.R1779W | Missense Mutation (SNP) | VAF 81/235 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.394); catalogued as rs973283650, COSV53563687; called by muse, mutect2, varscan2
- SLX4IP | c.316+1G>T p.X106_splice | Splice Site (SNP) | VAF 17/107 reads (16%) | catalogued as COSV100570412, COSV100570989; called by muse, mutect2, varscan2
- SOGA3 | c.722G>A p.G241D | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV100846885; called by muse, mutect2, varscan2
- SPSB4 | c.751C>A p.R251S | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.168); catalogued as COSV100141227, COSV60146317; called by muse, mutect2, varscan2
- SPZ1 | c.1036C>T p.Q346* | Nonsense Mutation (SNP) | VAF 19/110 reads (17%) | catalogued as COSV99698131; called by muse, mutect2, varscan2
- SSTR4 | c.78T>A p.S26R | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as COSV99658536; called by muse, mutect2, varscan2
- SYBU | c.589T>G p.S197A (on ENST00000276646 / NM_001099754.2; = p.S196A on NM_017786.6) | Missense Mutation (SNP) | VAF 68/557 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV99406037; called by muse, mutect2, varscan2
- TACC2 | c.2710C>G p.Q904E | Missense Mutation (SNP) | VAF 4/65 reads (6%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV57776222; called by muse, mutect2
- TAF1L | c.599T>G p.V200G | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.082); catalogued as COSV99644520; called by muse, mutect2, varscan2
- TCF7L2 | c.841C>G p.P281A (on ENST00000355995 / NM_001367943.1; = p.P258A on NM_030756.5) | Missense Mutation (SNP) | VAF 49/322 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.9); catalogued as COSV53344553, COSV53346102, COSV99525609; called by muse, mutect2, varscan2
- TEX44 | c.399G>T p.K133N | Missense Mutation (SNP) | VAF 27/166 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.241); catalogued as COSV100009709; called by muse, mutect2, varscan2
- TJP1 | c.2903C>T p.S968L | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); catalogued as COSV100632620; called by muse, mutect2, varscan2
- TLL1 | c.917G>T p.R306M | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50278495; called by muse, mutect2, varscan2
- TNR | c.20C>A p.T7K | Missense Mutation (SNP) | VAF 40/232 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.057); catalogued as COSV99689135; called by muse, mutect2
- TRERF1 | c.3183G>C p.Q1061H | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as COSV61680222; called by muse, mutect2, varscan2
- TRIM48 | c.466C>A p.L156I | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.263); catalogued as COSV101338259; called by muse, mutect2, varscan2
- TRPA1 | c.1949C>A p.S650Y | Missense Mutation (SNP) | VAF 20/152 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as COSV51556146; called by muse, mutect2, varscan2
- TRPM7 | c.3214T>G p.L1072V | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.803); catalogued as COSV100539743; called by muse, mutect2
- UNC13D | c.1708C>T p.R570C | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.326); catalogued as rs549768303, COSV99256524; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- USP20 | c.2035G>C p.V679L | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100204253, COSV59612424; called by muse, varscan2
- VANGL1 | c.622A>G p.I208V | Missense Mutation (SNP) | VAF 31/188 reads (16%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.526); catalogued as COSV100049066; called by muse, mutect2, varscan2
- WDR27 | c.1346T>C p.L449P | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs544443444, COSV100358648; called by muse, mutect2
- YTHDC2 | c.3220C>G p.L1074V | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.019); catalogued as COSV50749094, COSV99363173; called by muse, mutect2, varscan2
- ZFP64 | c.90C>G p.I30M | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99402290; called by muse, mutect2, varscan2
- ZMYND10 | c.908A>G p.Q303R | Missense Mutation (SNP) | VAF 31/163 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV99204910; called by muse, mutect2, varscan2
- ZNF217 | c.1406C>G p.S469C | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV100184396; called by muse, mutect2, varscan2
- ZNF493 | c.565G>T p.G189* | Nonsense Mutation (SNP) | VAF 10/71 reads (14%) | catalogued as COSV100828680, COSV62749331; called by muse, mutect2, varscan2
- ZNF518A | c.4289G>A p.S1430N | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as rs1269507256, COSV100283478; called by muse, mutect2
- ZNF676 | c.292A>G p.M98V (on ENST00000650058; = p.M66V on NM_001001411.3) | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1214474988, COSV101236172; called by muse, mutect2, varscan2
- ZNF695 | c.163C>G p.H55D | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.227); catalogued as COSV100377401; called by muse, mutect2, varscan2
- ZNF704 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 67/457 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as COSV59928357; called by muse, mutect2, varscan2
- ZNF93 | c.1514G>T p.G505V | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.829); catalogued as COSV100652254; called by muse, varscan2
- FCGBP | c.7079C>T p.P2360L | Missense Mutation (SNP) | VAF 26/381 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.948); called by muse, mutect2
- IGKV3D-20 | c.83C>A p.P28Q | Missense Mutation (SNP) | VAF 22/193 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- LHX1 | c.1014C>G p.S338R | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated (0.06); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- NF1 | c.5812+5_5812+8del p.X1938_splice (on ENST00000358273 / NM_001042492.3; = p.X1917_splice on NM_000267.3) | Splice Site (DEL) | VAF 16/58 reads (28%) | called by pindel, varscan2
- OR51M1 | c.759del p.C253* | Frame Shift Del (DEL) | VAF 12/101 reads (12%) | called by mutect2, pindel, varscan2
- SOCS7 | c.1151-1G>C p.X384_splice | Splice Site (SNP) | VAF 29/78 reads (37%) | called by muse, mutect2, varscan2
- ST3GAL6 | c.74del p.G25Efs*12 | Frame Shift Del (DEL) | VAF 22/184 reads (12%) | called by mutect2, pindel, varscan2
- TRBJ2-6 | c.37A>T p.S13C | Missense Mutation (SNP) | VAF 13/90 reads (14%) | called by muse, mutect2, varscan2
- USP20 | c.1989delinsGA p.Y663* | Nonsense Mutation (INS) | VAF 9/47 reads (19%) | called by pindel, varscan2*
- ABCG2 | c.1629C>T p.I543= | Silent (SNP) | VAF 11/84 reads (13%) | catalogued as COSV99419087; called by muse, mutect2, varscan2
- ACTN3 | c.669T>C p.F223= | Silent (SNP) | VAF 45/248 reads (18%) | catalogued as COSV101557829; called by muse, mutect2, varscan2
- ADAMTS4 | c.1098C>A p.V366= | Silent (SNP) | VAF 22/162 reads (14%) | catalogued as COSV100917423; called by muse, varscan2
- AGAP3 | c.2625A>G p.L875= (on ENST00000622464; = p.L911= on NM_031946.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 17/85 reads (20%) | catalogued as rs571412298, COSV99880857; called by muse, mutect2, varscan2
- AHNAK2 | c.6594C>A p.T2198= | Silent (SNP) | VAF 16/311 reads (5%) | catalogued as COSV100317059; called by muse, mutect2
- ALDH3B2 | c.483G>A p.Q161= | Silent (SNP) | VAF 18/257 reads (7%) | catalogued as rs746190408, COSV100824021; called by muse, mutect2
- AMER3 | c.315G>C p.T105= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as COSV100366409; called by muse, mutect2, varscan2
- APOBEC4 | c.237G>T p.V79= | Silent (SNP) | VAF 23/112 reads (21%) | catalogued as COSV100426107; called by muse, mutect2, varscan2
- BCAN | c.763C>T p.L255= | Silent (SNP) | VAF 33/254 reads (13%) | catalogued as COSV100228045; called by muse, mutect2, varscan2
- CACNA1B | c.447C>T p.I149= | Silent (SNP) | VAF 14/99 reads (14%) | catalogued as COSV99496830; called by muse, mutect2, varscan2
- CAPS2 | c.1605C>T p.G535= | Silent (SNP) | VAF 29/220 reads (13%) | catalogued as COSV100157627; called by muse, mutect2, varscan2
- CEP192 | c.5247A>G p.S1749= | Silent (SNP) | VAF 14/103 reads (14%) | catalogued as COSV100381053; called by muse, mutect2, varscan2
- CYP11B2 | c.213C>A p.T71= | Silent (SNP) | VAF 43/136 reads (32%) | catalogued as COSV100010953, COSV100011489; called by muse, mutect2, varscan2
- CYP4F11 | c.162C>A p.P54= | Silent (SNP) | VAF 32/173 reads (18%) | catalogued as COSV99930813; called by muse, mutect2, varscan2
- DCAF4L2 | c.315A>T p.R105= | Silent (SNP) | VAF 39/248 reads (16%) | catalogued as COSV100150784; called by muse, mutect2, varscan2
- DCDC1 | c.3600G>T p.V1200= (on ENST00000597505 / NM_001367979.1; = p.V307= on NM_020869.3) | Silent (SNP) | VAF 26/202 reads (13%) | catalogued as COSV100338120; called by muse, mutect2, varscan2
- DHX57 | c.843G>C p.L281= | Silent (SNP) | VAF 17/98 reads (17%) | catalogued as COSV99769378; called by muse, mutect2, varscan2
- DSCC1 | c.249G>A p.L83= | Silent (SNP) | VAF 36/120 reads (30%) | catalogued as COSV100558306; called by muse, mutect2, varscan2
- ERBB3 | c.1758G>C p.V586= | Silent (SNP) | VAF 20/226 reads (9%) | catalogued as COSV99916609; called by muse, mutect2
- FAM91A1 | c.996A>G p.S332= | Silent (SNP) | VAF 54/197 reads (27%) | catalogued as rs373637439; called by muse, mutect2, varscan2
- FAN1 | c.2913T>C p.F971= | Silent (SNP) | VAF 22/146 reads (15%) | catalogued as rs1307068495, COSV100755939; called by muse, mutect2, varscan2
- FRG2B | c.72C>T p.F24= | Silent (SNP) | VAF 88/322 reads (27%) | catalogued as COSV71044241; called by muse, mutect2
- FRG2C | c.72C>T p.F24= | Silent (SNP) | VAF 58/263 reads (22%) | called by mutect2, varscan2
- FZD7 | c.387G>A p.Q129= | Silent (SNP) | VAF 14/160 reads (9%) | catalogued as rs769095759, COSV99637094; called by muse, mutect2
- GCG | c.388C>A p.R130= | Silent (SNP) | VAF 24/176 reads (14%) | catalogued as COSV64961045; called by muse, mutect2, varscan2
- GSDMC | c.39C>G p.V13= | Silent (SNP) | VAF 23/245 reads (9%) | catalogued as rs1443709295, COSV99415881; called by muse, mutect2
- HCN1 | c.714T>A p.I238= | Silent (SNP) | VAF 9/56 reads (16%) | catalogued as COSV100299843; called by muse, mutect2, varscan2
- IGFN1 | c.2158C>A p.R720= (on ENST00000295591 / NM_001367841.1; = p.R3177= on NM_001164586.2) | Silent (SNP) | VAF 31/182 reads (17%) | catalogued as COSV55170702, COSV99811975; called by muse, mutect2, varscan2
- IGKV3-7 | c.57C>T p.T19= | Silent (SNP) | VAF 22/181 reads (12%) | catalogued as rs1410429363; called by muse, mutect2, varscan2
- INCENP | c.768G>A p.K256= | Silent (SNP) | VAF 24/156 reads (15%) | catalogued as COSV99610920; called by muse, mutect2, varscan2
- ISG20 | c.399G>A p.L133= | Silent (SNP) | VAF 24/109 reads (22%) | catalogued as rs1424000521, COSV100043929, COSV60144561; called by muse, mutect2, varscan2
- KIAA1328 | c.1281T>A p.S427= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV99694064; called by muse, mutect2, varscan2
- KRT75 | c.957C>T p.I319= | Silent (SNP) | VAF 47/299 reads (16%) | catalogued as COSV99359364; called by muse, mutect2, varscan2
- LAMP1 | c.792G>A p.S264= | Silent (SNP) | VAF 36/278 reads (13%) | catalogued as rs768014512, COSV100208582; called by muse, mutect2, varscan2
- LGI3 | c.777C>T p.I259= | Silent (SNP) | VAF 36/169 reads (21%) | catalogued as COSV100103002; called by muse, mutect2, varscan2
- LHB | c.417C>G p.L139= | Silent (SNP) | VAF 18/125 reads (14%) | catalogued as COSV99668960; called by muse, mutect2, varscan2
- LPA | c.4434G>A p.V1478= | Silent (SNP) | VAF 25/197 reads (13%) | catalogued as COSV100306669; called by muse, mutect2, varscan2
- MAP4K1 | c.1656C>G p.L552= | Silent (SNP) | VAF 49/408 reads (12%) | catalogued as COSV101204197; called by muse, mutect2, varscan2
- MARS2 | c.105T>C p.S35= | Silent (SNP) | VAF 14/104 reads (13%) | catalogued as COSV99986565; called by muse, mutect2, varscan2
- MUC5B | c.10369C>A p.R3457= | Silent (SNP) | VAF 18/114 reads (16%) | catalogued as COSV101500266, COSV71590189; called by muse, mutect2, varscan2
- MYH13 | c.954A>T p.G318= | Silent (SNP) | VAF 79/209 reads (38%) | catalogued as COSV99353567; called by muse, mutect2, varscan2
- NMUR1 | c.30C>T p.V10= | Silent (SNP) | VAF 7/69 reads (10%) | catalogued as COSV100531922; called by muse, mutect2, varscan2
- OPN3 | c.181C>T p.L61= | Silent (SNP) | VAF 6/74 reads (8%) | catalogued as rs1450411886, COSV100087293; called by muse, mutect2
- OR8K3 | c.117G>A p.V39= | Silent (SNP) | VAF 32/194 reads (16%) | catalogued as COSV100449671; called by muse, varscan2
- PGM1 | c.150G>A p.A50= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as rs1251527971, COSV100936787; called by muse, mutect2, varscan2
- PHRF1 | c.4002C>T p.P1334= (on ENST00000264555 / NM_001286581.2; = p.P1333= on NM_020901.4) | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as rs535717915, COSV99199906; called by muse, mutect2, varscan2
- RYR3 | c.2901T>A p.P967= | Silent (SNP) | VAF 19/140 reads (14%) | catalogued as COSV101212553; called by muse, mutect2, varscan2
- SIPA1L1 | c.741C>T p.L247= | Silent (SNP) | VAF 23/105 reads (22%) | catalogued as rs917800629, COSV100665437; called by muse, mutect2, varscan2
- SLC25A45 | c.252C>G p.L84= | Silent (SNP) | VAF 20/123 reads (16%) | catalogued as COSV99587289; called by muse, mutect2, varscan2
- SRCAP | c.3390C>G p.P1130= | Silent (SNP) | VAF 18/243 reads (7%) | catalogued as rs934792654, COSV99349918; called by muse, mutect2
- TACC2 | c.2934C>T p.F978= | Silent (SNP) | VAF 7/104 reads (7%) | catalogued as COSV100552177; called by muse, mutect2
- TM6SF2 | c.519C>T p.F173= | Silent (SNP) | VAF 4/78 reads (5%) | catalogued as COSV101231591; called by muse, mutect2
- TMEM132D | c.528C>G p.T176= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as rs745411009, COSV101397450, COSV70611344; called by muse, mutect2, varscan2
- UNC13A | c.3492G>T p.L1164= | Silent (SNP) | VAF 15/171 reads (9%) | catalogued as COSV99407983; called by muse, mutect2, varscan2
- UNC5D | c.1833C>T p.I611= | Silent (SNP) | VAF 33/267 reads (12%) | catalogued as rs369520847, COSV54811377; called by muse, mutect2, varscan2
- ZAN | c.2319C>T p.L773= | Silent (SNP) | VAF 33/201 reads (16%) | catalogued as COSV100769611; called by muse, mutect2, varscan2
- BCAS1 | c.927+2401T>A | Intron (SNP) | VAF 6/55 reads (11%) | catalogued as COSV101006142; called by muse, mutect2, varscan2
- MACF1 | c.15832-9932A>G | Intron (SNP) | VAF 11/82 reads (13%) | catalogued as rs1221389052, COSV99243553; called by muse, mutect2, varscan2
- OR8K3 | c.-2G>T | 5'UTR (SNP) | VAF 14/104 reads (13%) | catalogued as COSV100449744; called by muse, varscan2
- RC3H2 | c.961-160G>T | Intron (SNP) | VAF 15/109 reads (14%) | catalogued as COSV100106500; called by muse, mutect2, varscan2
- RNU7-174P | chr8:80559357 G>A | 5'Flank (SNP) | VAF 36/141 reads (26%) | called by muse, mutect2, varscan2
